Somatic mutation profile of tumor specimen TCGA-19-5955-01A (aliquot TCGA-19-5955-01A-11D-1696-08) from TCGA case TCGA-19-5955, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 83.6 years (30,550 days).
Specimen TCGA-19-5955-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e212437-4e48-4a9e-8ef4-3a9b6c2ca80f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-5955-10A (Blood Derived Normal), aliquot TCGA-19-5955-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f77ec1a9-fce2-45c4-99d1-2229e945b414

The open-access MAF lists 69 somatic variants for this specimen: 48 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 20, Nonsense Mutation 4, Frame Shift Del 3, Splice Region 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1746-2A>G p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 16/90 reads (18%) | hotspot (GDC flag); catalogued as COSV57125460, COSV57131831, COSV57142185; called by muse, mutect2, varscan2
- ABCC3 | c.3725G>A p.W1242* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV53322889; called by muse, mutect2, varscan2
- ADAM29 | c.2287G>C p.V763L | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV63662860, COSV63664049; called by muse, mutect2, varscan2
- ASTN2 | c.2636A>G p.N879S (on ENST00000313400 / NM_001365069.1; = p.N828S on NM_014010.5) | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.192); catalogued as COSV57782092; called by muse, mutect2, varscan2
- C12orf43 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV56567384; called by muse, mutect2
- CLDN15 | c.338A>G p.K113R | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57659069; called by muse, mutect2, varscan2
- CLSTN2 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); catalogued as rs750759979, COSV71721153; called by muse, mutect2, varscan2
- COL1A1 | c.4008C>T p.F1336= | Splice Region (SNP) | VAF 11/70 reads (16%) | catalogued as rs763676384, COSV56802169; called by muse, mutect2, varscan2
- CSN2 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV61992044; called by muse, mutect2, varscan2
- EBF2 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 20/111 reads (18%) | catalogued as COSV68776285; called by muse, mutect2, varscan2
- ERICH3 | c.3998G>A p.G1333E | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV58601275; called by muse, mutect2, varscan2
- GRM8 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as rs780568800, COSV58821868; called by muse, mutect2, varscan2
- HS3ST6 | c.416G>T p.S139I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as COSV53534882; called by muse, mutect2, varscan2
- HTR7 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as COSV53287218; called by muse, mutect2, varscan2
- IFNL3 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs540120208, COSV69830002; called by muse, mutect2
- IKZF1 | c.1476C>A p.C492* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV58786321; called by muse, mutect2
- KLC3 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373353596; called by muse, mutect2, varscan2
- MACO1 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.839); catalogued as rs1371693575, COSV65476633; called by muse, mutect2, varscan2
- MROH8 | c.134T>G p.L45R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54120459; called by muse, mutect2, varscan2
- MUC16 | c.29300A>G p.K9767R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.012); catalogued as COSV67469529; called by muse, mutect2, varscan2
- MYO3A | c.822del p.K274Nfs*22 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as COSV56352153, COSV99781351; called by mutect2, pindel, varscan2
- OR2M2 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 48/271 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs775272894, COSV62897939; called by muse, mutect2, varscan2
- PABPC1 | c.195G>A p.A65= | Splice Region (SNP) | VAF 6/42 reads (14%) | catalogued as rs751412519, COSV59401994; called by muse, mutect2
- PCDHA11 | c.1240C>A p.R414S | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs375366430, COSV104408198, COSV56506934; called by muse, mutect2
- PCDHA11 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782475792, COSV56483734; called by muse, mutect2
- PCDHB14 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as COSV53386625; called by muse, mutect2, varscan2
- PCDHB7 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.055); catalogued as COSV50772695; called by muse, mutect2, varscan2
- PIM2 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55944820; called by muse, mutect2, varscan2
- PKHD1 | c.10508T>C p.L3503P | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV100943717; called by muse, mutect2, varscan2
- PTEN | c.1113del p.D371Efs*45 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as COSV64293747; called by mutect2, pindel, varscan2
- RNF17 | c.3051T>A p.N1017K | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.363); catalogued as COSV55041393; called by muse, mutect2, varscan2
- RRAGA | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65843112, COSV65843569; called by muse, mutect2, varscan2
- RTN1 | c.510G>C p.M170I | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV50726386; called by muse, mutect2
- RTN1 | c.272A>G p.H91R | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV50726427; called by muse, mutect2, varscan2
- SEPTIN9 | c.707C>T p.P236L (on ENST00000427177 / NM_001113491.2; = p.P218L on NM_006640.4) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV61205430; called by muse, mutect2, varscan2
- SIRPD | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 23/109 reads (21%) | PolyPhen benign (0.003); catalogued as rs181823552; called by muse, mutect2, varscan2
- SLC7A13 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV99878531; called by muse, mutect2, varscan2
- SMCHD1 | c.1575A>C p.K525N | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55258402; called by muse, mutect2, varscan2
- SRSF11 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as COSV63937109; called by muse, mutect2, varscan2
- ST8SIA1 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as rs745747495, COSV53951274; called by muse, mutect2, varscan2
- STC1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.27); catalogued as rs778531998, COSV51688654; called by muse, mutect2, varscan2
- TAF1L | c.3238C>T p.R1080C | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs756949456, COSV54260497, COSV54262664; called by muse, mutect2, varscan2
- TEP1 | c.758G>C p.C253S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV52993333; called by muse, mutect2
- TMEM143 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1242619832, COSV53156706, COSV99035520; called by muse, mutect2, varscan2
- TMEM150B | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV58593823; called by muse, mutect2, varscan2
- TTN | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 25/114 reads (22%) | PolyPhen benign (0.003); catalogued as rs372755739; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDFY3 | c.2834G>A p.R945H | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs766953747, COSV55702346; called by muse, mutect2, varscan2
- ATM | c.7225del p.E2409Nfs*9 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | called by mutect2, pindel, varscan2
- ACACA | c.778T>C p.L260= | Silent (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- BTBD9 | c.1434G>A p.P478= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as rs181693343, COSV58422155; called by muse, mutect2, varscan2
- CWH43 | c.1776A>C p.L592= | Silent (SNP) | VAF 45/273 reads (16%) | catalogued as COSV56939377; called by muse, mutect2, varscan2
- FCN2 | c.306G>A p.P102= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs369807019, COSV52477223; called by muse, mutect2, varscan2
- FGD3 | c.297C>T p.G99= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV61597650; called by muse, mutect2, varscan2
- FREM1 | c.4752G>A p.G1584= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as rs750470197, COSV66521069; called by muse, mutect2, varscan2
- GAA | c.1392G>A p.R464= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as COSV56408948; called by muse, mutect2, varscan2
- GRIP1 | c.2979G>A p.E993= (on ENST00000359742 / NM_001379345.1; = p.E941= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as COSV54025732; called by muse, mutect2, varscan2
- L1CAM | c.3444C>T p.G1148= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs201721767, COSV62828295; called by mutect2, varscan2
- LYN | c.678T>C p.C226= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as rs760894198, COSV70205741; called by muse, mutect2, varscan2
- NEDD4 | c.3141C>T p.N1047= (on ENST00000508342 / NM_001284338.1; = p.N628= on NM_006154.4) | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as rs746998179, COSV59062314; called by muse, mutect2
- NOVA1 | c.483T>G p.S161= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV57477885; called by muse, mutect2, varscan2
- OR2T27 | c.777C>T p.Y259= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs370373865, COSV100788468, COSV61281098, COSV61281472; called by muse, mutect2
- OR4D10 | c.348G>A p.S116= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs763075726, COSV101597012, COSV73260038; called by muse, mutect2, varscan2
- PRDM14 | c.792A>G p.P264= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV52572753; called by muse, mutect2, varscan2
- RIMS2 | c.621T>C p.H207= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV68113143; called by muse, mutect2, varscan2
- SOX9 | c.1353C>T p.Y451= | Silent (SNP) | VAF 38/187 reads (20%) | catalogued as COSV55424682, COSV55427541; called by muse, mutect2, varscan2
- TEP1 | c.756G>C p.L252= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV52993347; called by muse, mutect2
- TICAM1 | c.579C>T p.S193= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as rs1362028513, COSV50232836; called by muse, mutect2, varscan2
- TTN | c.61506C>T p.D20502= (on ENST00000591111; = p.D13078= on NM_003319.4) | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs1367041984, COSV60099031; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM27E5 | n.373G>A | RNA (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
